Somatic mutation profile of tumor specimen ALCH-B1KX-TTP1-A (aliquot ALCH-B1KX-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1KX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.6 years (21,047 days).
Specimen ALCH-B1KX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b537b0cf-c9f8-4499-b2a4-117847a143c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1KX-NB1-A (Blood Derived Normal), aliquot ALCH-B1KX-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/98f4301c-f532-4e3e-9601-3bc9cc7cea05

The open-access MAF lists 482 somatic variants for this specimen: 342 protein-altering or splice-affecting, 86 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 288, Silent 86, Nonsense Mutation 31, Intron 31, Splice Site 14, 3'UTR 8, RNA 7, 5'UTR 4, Splice Region 4, Frame Shift Del 3, 3'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 20/214 reads (9%) | hotspot (GDC flag); catalogued as rs730882001, COSV52677910, COSV52844585, COSV53637782; ClinVar: pathogenic; called by muse, mutect2
- ABCA6 | c.261G>T p.Q87H | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV99447627; called by muse, mutect2, varscan2
- ABCB4 | c.834G>T p.R278S | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV55937466; called by muse, mutect2
- ADAMTS20 | c.1946G>T p.G649V | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as rs1178408955, COSV101239231; called by muse, mutect2
- ADGRB1 | c.2707C>A p.P903T | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs974310200; called by muse, mutect2, varscan2
- ADGRG4 | c.7634G>T p.R2545L | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs752548011, COSV54957269, COSV54967489; called by muse, mutect2, varscan2
- ARID1A | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 25/550 reads (5%) | catalogued as COSV61377807; called by muse, mutect2
- B3GNT3 | c.830G>T p.R277L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.741); catalogued as COSV57952664; called by muse, mutect2
- C17orf99 | c.640+8G>A | Splice Region (SNP) | VAF 19/201 reads (9%) | catalogued as rs1468757418; called by muse, mutect2
- CACNA1D | c.2092G>A p.V698M (on ENST00000350061 / NM_001128840.3; = p.V718M on NM_000720.4) | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1370436980; called by muse, mutect2
- CAPRIN2 | c.2788C>A p.P930T | Missense Mutation (SNP) | VAF 26/357 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.288); catalogued as COSV51831061; called by muse, mutect2
- CD86 | c.894-1G>T p.X298_splice (on ENST00000330540 / NM_175862.5; = p.X292_splice on NM_006889.4) | Splice Site (SNP) | VAF 14/369 reads (4%) | catalogued as COSV100053817; called by muse, mutect2
- CDKAL1 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 10/287 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV51182951, COSV51194083; called by muse, mutect2
- CEP290 | c.739G>T p.V247L | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as CD156700; called by muse, mutect2
- CR1 | c.3637C>A p.Q1213K | Missense Mutation (SNP) | VAF 29/200 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100887468; called by muse, mutect2, varscan2
- CSMD3 | c.4960C>G p.L1654V (on ENST00000297405 / NM_001363185.1; = p.L1550V on NM_052900.3) | Missense Mutation (SNP) | VAF 18/307 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV52094276, COSV52328651; called by muse, mutect2
- CSMD3 | c.4826C>T p.P1609L (on ENST00000297405 / NM_001363185.1; = p.P1505L on NM_052900.3) | Missense Mutation (SNP) | VAF 44/636 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1196558347, COSV52113614; called by muse, mutect2
- CSMD3 | c.4825C>A p.P1609T (on ENST00000297405 / NM_001363185.1; = p.P1505T on NM_052900.3) | Missense Mutation (SNP) | VAF 44/638 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52313045; called by muse, mutect2
- CSMD3 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 23/348 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52105591, COSV52111082; called by muse, mutect2
- DCX | c.807T>C p.N269= | Splice Region (SNP) | VAF 22/208 reads (11%) | catalogued as rs778492306, COSV104403142; called by muse, mutect2
- DIO3 | c.637C>G p.P213A | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.852); catalogued as COSV63774726; called by muse, mutect2
- DNAH3 | c.10385G>T p.G3462V | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.424); catalogued as COSV54511387; called by muse, mutect2
- DOCK2 | c.2723T>G p.I908S | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV56939831; called by muse, mutect2
- E2F3 | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 26/335 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60900011; called by muse, mutect2
- ECEL1 | c.2294C>G p.P765R | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV100458470; called by muse, mutect2
- EPC2 | c.2410A>G p.M804V | Missense Mutation (SNP) | VAF 26/349 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs762583688; called by muse, mutect2
- EQTN | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 12/121 reads (10%) | catalogued as rs142257398; called by muse, mutect2
- EXOC6B | c.1939G>T p.A647S | Missense Mutation (SNP) | VAF 32/425 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.3); catalogued as rs765619390; called by muse, mutect2
- F7 | c.1272G>T p.W424C | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM001993, CM010254; called by muse, mutect2
- FAM47A | c.1634C>A p.P545Q | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.238); catalogued as COSV60496012, COSV60498636; called by muse, varscan2
- FLG | c.1013C>A p.S338Y | Missense Mutation (SNP) | VAF 61/563 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); catalogued as COSV64251179; called by muse, mutect2, varscan2
- FLT1 | c.2062C>A p.P688T | Missense Mutation (SNP) | VAF 26/608 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99030703; called by muse, mutect2
- GAB4 | c.110G>T p.S37I | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as COSV68753837, COSV68754377; called by muse, mutect2
- GRID1 | c.2549C>A p.A850D | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.368); catalogued as COSV60058388; called by muse, mutect2
- GTPBP1 | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as COSV53286588; called by muse, mutect2
- HRNR | c.975C>A p.H325Q | Missense Mutation (SNP) | VAF 25/312 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV64261673; called by muse, mutect2
- IFNA13 | c.431T>C p.V144A | Missense Mutation (SNP) | VAF 19/306 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768784838; called by muse, varscan2
- IRS4 | c.419del p.P140Rfs*8 | Frame Shift Del (DEL) | VAF 12/120 reads (10%) | catalogued as COSV100929746; called by mutect2, varscan2
- ITGAX | c.1515G>A p.W505* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV51641889; called by muse, mutect2, varscan2
- KIR2DS4 | c.599C>A p.T200K | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.475); catalogued as rs760743437; called by muse, mutect2, varscan2
- KLHL34 | c.693C>A p.D231E | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV65278721; called by muse, mutect2
- KRT6A | c.1673G>A p.S558N | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs1265199899; called by muse, mutect2
- LPO | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51860346; called by muse, mutect2
- LYST | c.9233G>A p.R3078H | Missense Mutation (SNP) | VAF 17/259 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764697537; called by muse, mutect2
- MAGEA12 | c.652G>T p.E218* | Nonsense Mutation (SNP) | VAF 32/227 reads (14%) | catalogued as COSV63294767, COSV63295395; called by muse, mutect2, varscan2
- MATN2 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.131); catalogued as COSV99646105; called by mutect2, varscan2
- MPDZ | c.2255T>C p.M752T | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1231959718; called by muse, mutect2
- MSR1 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 19/381 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as COSV50521391; called by muse, mutect2
- MTM1 | c.1165del p.A389Pfs*3 | Frame Shift Del (DEL) | VAF 18/219 reads (8%) | catalogued as COSV60335011; called by mutect2, pindel*
- NAP1L2 | c.248C>A p.S83* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | catalogued as COSV65172563; called by muse, mutect2, varscan2
- NAV3 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs1260108374, COSV57078764, COSV99895352; called by muse, mutect2
- NEK10 | c.1046C>G p.S349C | Missense Mutation (SNP) | VAF 37/358 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as rs1259339559; called by muse, mutect2
- NF2 | c.1447-1G>A p.X483_splice | Splice Site (SNP) | VAF 24/440 reads (5%) | catalogued as CS115648, CS115649; called by muse, mutect2
- NPC1L1 | c.3088G>T p.A1030S | Missense Mutation (SNP) | VAF 12/376 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs1563202641; called by muse, mutect2
- NPR2 | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 60/558 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as CM140241; called by muse, mutect2
- NRXN1 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 29/413 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.901); catalogued as rs201643971, COSV58458190; called by muse, mutect2
- OPCML | c.592G>T p.G198W | Missense Mutation (SNP) | VAF 10/261 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59458581; called by muse, mutect2
- OR2J1 | c.749C>A p.S250Y | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV65850626; called by muse, mutect2
- OR4C15 | c.889A>G p.I297V (on ENST00000314644; = p.I243V on NM_001001920.2) | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.263); catalogued as COSV58952489; called by muse, mutect2
- OR4S2 | c.494C>A p.P165H | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as rs774475058; called by muse, mutect2
- OR52D1 | c.492C>A p.F164L | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV59487377; called by muse, mutect2
- OR6F1 | c.911A>C p.K304T | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV57468491; called by muse, mutect2
- OR8H1 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as rs368340807; called by muse, mutect2
- PAX6 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 49/414 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM083006, COSV53793520; called by muse, mutect2, varscan2
- PCDHB9 | c.401G>T p.R134L | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.313); catalogued as rs1554282833, COSV53377395; called by muse, mutect2
- PCDHGA2 | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.049); catalogued as COSV54013462; called by muse, mutect2
- PCDHGA3 | c.1789G>T p.D597Y | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs962753490; called by muse, mutect2
- PFKFB4 | c.331C>T p.L111F | Missense Mutation (SNP) | VAF 18/296 reads (6%) | PolyPhen probably damaging (0.995); catalogued as rs1273288705; called by muse, mutect2
- PPP1R12C | c.800C>A p.A267E | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99670349; called by muse, mutect2, varscan2
- PPP1R3A | c.1994C>G p.S665* | Nonsense Mutation (SNP) | VAF 55/522 reads (11%) | catalogued as COSV52882141; called by muse, mutect2, varscan2
- PRKCB | c.1267G>T p.V423L | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.668); catalogued as rs1447848733, COSV100335524; called by muse, mutect2
- PSG2 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 66/444 reads (15%) | catalogued as rs149645996; called by muse, mutect2, varscan2
- RGPD3 | c.3115G>T p.E1039* | Nonsense Mutation (SNP) | VAF 38/867 reads (4%) | catalogued as COSV58742991; called by muse, mutect2
- RGS18 | c.164C>A p.P55H | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs768744391; called by muse, mutect2
- RP1 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759385909; called by mutect2, varscan2
- RYK | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 33/323 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56063497; called by muse, mutect2
- S100A2 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.131); catalogued as rs1208378423; called by muse, mutect2
- SHPRH | c.3046T>A p.C1016S (on ENST00000275233 / NM_001042683.3; = p.C1025S on NM_173082.3) | Missense Mutation (SNP) | VAF 16/343 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV104368229; called by muse, mutect2
- SKOR2 | c.182G>C p.R61P | Missense Mutation (SNP) | VAF 19/378 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101247199; called by muse, mutect2
- SLC13A3 | c.559G>C p.G187R | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as COSV99285938; called by muse, mutect2
- SLITRK2 | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59428955; called by muse, mutect2, varscan2
- SLITRK6 | c.1629C>A p.D543E | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375655378; called by muse, mutect2, varscan2
- SP140 | c.1646-1G>A p.X549_splice | Splice Site (SNP) | VAF 13/208 reads (6%) | catalogued as COSV100613642; called by muse, mutect2
- SP140L | c.1282G>T p.D428Y | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.288); catalogued as rs1183221748; called by muse, mutect2
- SPSB4 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV60150694; called by muse, mutect2
- SULT6B1 | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV53195325; called by muse, mutect2
- SYNE1 | c.121C>G p.L41V | Missense Mutation (SNP) | VAF 30/440 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV54897522, COSV99562439; called by muse, mutect2
- TCHH | c.3644G>C p.R1215P | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.774); catalogued as COSV100914913; called by muse, mutect2
- TENM2 | c.1434C>A p.F478L (on ENST00000518659 / NM_001122679.2; = p.F246L on NM_001080428.3) | Missense Mutation (SNP) | VAF 15/421 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV101317894; called by muse, mutect2
- TFEB | c.1306A>G p.M436V | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as rs1200035703; called by muse, mutect2
- TMPRSS3 | c.633G>T p.R211S | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV52308009; called by muse, mutect2
- TNKS | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.41); catalogued as COSV60056653; called by muse, mutect2, varscan2
- TP53 | c.492G>T p.K164N | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53165155, COSV53219732, COSV53700637; called by muse, mutect2
- TSC2 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 31/425 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201144475; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- TTC5 | c.586A>G p.T196A | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1219207285; called by muse, mutect2
- WDR1 | c.596C>T p.P199L (on ENST00000382452; = p.P59L on NM_005112.5) | Missense Mutation (SNP) | VAF 12/349 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs949325461; called by muse, mutect2
- ZADH2 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568345284; called by muse, mutect2
- ZNF705G | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 21/470 reads (4%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.95); catalogued as rs748280758; called by muse, mutect2
- AC092143.1 | c.1465G>T p.G489C | Missense Mutation (SNP) | VAF 31/317 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC131160.1 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 34/492 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACTL8 | c.278A>T p.Q93L | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2
- ADAM30 | c.1355C>G p.P452R | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ADGRD1 | c.1304T>G p.L435R | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2
- AJM1 | c.1754C>A p.T585K | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2
- AKAP6 | c.4966G>C p.D1656H | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AL445989.1 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 34/566 reads (6%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2
- ALDH1A2 | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALDH3A1 | c.1216+1G>A p.X406_splice | Splice Site (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- ALDH3A1 | c.1216G>T p.G406W | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ALDH9A1 | c.593-2A>T p.X198_splice | Splice Site (SNP) | VAF 6/101 reads (6%) | called by muse, mutect2
- ALOX15B | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2
- AMMECR1 | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ANK1 | c.1880C>G p.S627* | Nonsense Mutation (SNP) | VAF 20/329 reads (6%) | called by muse, mutect2
- ANKS6 | c.867G>T p.E289D | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.155); called by muse, mutect2
- ANO3 | c.1085G>A p.R362K | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ANO5 | c.566C>A p.A189E | Missense Mutation (SNP) | VAF 32/315 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- APBA2 | c.353G>T p.G118V | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); called by muse, mutect2
- APOB | c.8059C>A p.P2687T | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2
- ARHGAP6 | c.1809+1G>T p.X603_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.1809G>A p.M603I | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- ARHGEF26 | c.1865A>G p.E622G | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ASB2 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 18/376 reads (5%) | called by muse, mutect2
- ASTN1 | c.1464C>A p.Y488* | Nonsense Mutation (SNP) | VAF 15/258 reads (6%) | called by muse, mutect2
- B3GAT2 | c.602C>A p.T201N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- BAHCC1 | c.2560G>T p.A854S | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.613); called by muse, mutect2
- BBS7 | c.785A>T p.D262V | Missense Mutation (SNP) | VAF 15/288 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- BCL6B | c.591C>A p.Y197* | Nonsense Mutation (SNP) | VAF 33/272 reads (12%) | called by muse, mutect2, varscan2
- C8B | c.392-1G>C p.X131_splice | Splice Site (SNP) | VAF 18/552 reads (3%) | called by muse, mutect2
- C8orf33 | c.13G>C p.G5R | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2
- CACNA1C | c.2080C>A p.Q694K | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- CACNA1G | c.2092C>A p.Q698K | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.647); called by muse, mutect2
- CALML5 | c.310A>T p.R104W | Missense Mutation (SNP) | VAF 24/242 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2
- CAPG | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 21/216 reads (10%) | called by muse, mutect2
- CCDC166 | c.1075C>A p.P359T | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- CCDC89 | c.315G>C p.M105I | Missense Mutation (SNP) | VAF 26/425 reads (6%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- CD34 | c.53C>A p.T18N | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.368); called by muse, mutect2
- CDH9 | c.157C>G p.R53G | Missense Mutation (SNP) | VAF 41/425 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDHR3 | c.1178G>A p.S393N | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CDK5RAP1 | c.808A>G p.T270A | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CEP162 | c.1891G>T p.A631S | Missense Mutation (SNP) | VAF 28/542 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.027); called by muse, mutect2
- CEP250 | c.4540G>T p.E1514* | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- CEP89 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.09); called by muse, mutect2
- CERK | c.291del p.W97* | Frame Shift Del (DEL) | VAF 14/147 reads (10%) | called by mutect2, pindel, varscan2
- CES1 | c.1118T>A p.L373Q (on ENST00000361503 / NM_001025194.2; = p.L372Q on NM_001266.5) | Missense Mutation (SNP) | VAF 30/583 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CFAP46 | c.7887C>G p.S2629R | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIAO2A | c.155A>T p.K52M | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- CNTN1 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 16/332 reads (5%) | called by muse, mutect2
- CNTN1 | c.740A>T p.Q247L | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.136); called by muse, mutect2
- COL20A1 | c.2572T>A p.S858T | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.514); called by muse, mutect2
- COL24A1 | c.2471C>A p.P824Q | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); called by muse, mutect2
- COL4A4 | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 20/512 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- COL6A5 | c.4618G>T p.G1540* | Nonsense Mutation (SNP) | VAF 16/252 reads (6%) | called by muse, mutect2
- COL6A6 | c.3030C>A p.S1010R | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- COPA | c.1216G>T p.D406Y | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2
- CORIN | c.1404C>A p.Y468* | Nonsense Mutation (SNP) | VAF 12/252 reads (5%) | called by muse, mutect2
- CRB1 | c.2596C>A p.P866T | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2
- CSTF2T | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.175); called by muse, mutect2
- CYFIP1 | c.2168T>C p.L723P | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CYP4F8 | c.1314+1G>T p.X438_splice | Splice Site (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2
- DACT2 | c.1469G>T p.G490V | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2
- DGKK | c.1162C>A p.L388I | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DGKZ | c.2767-2A>G p.X923_splice (on ENST00000454345 / NM_001105540.2; = p.X735_splice on NM_003646.4) | Splice Site (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- DNAAF5 | c.752C>A p.A251D | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DOC2A | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DOCK1 | c.5216A>G p.Q1739R | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.838); called by muse, mutect2
- DPYSL4 | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DST | c.14980A>G p.I4994V (on ENST00000361203 / NM_001374722.1; = p.I2582V on NM_015548.5) | Missense Mutation (SNP) | VAF 35/357 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2
- DST | c.2795C>A p.A932D (on ENST00000361203 / NM_001374722.1; = p.A606D on NM_001723.6) | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DUOXA2 | c.953C>T p.T318I | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- EDEM1 | c.1096G>T p.G366C | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EFCAB14 | c.616C>T p.H206Y | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.439); called by muse, mutect2
- ELF1 | c.1156G>T p.V386F | Missense Mutation (SNP) | VAF 13/365 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2
- ELFN1 | c.262T>A p.Y88N | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2
- EPHA6 | c.1713G>T p.E571D | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.737); called by muse, mutect2
- ERICH3 | c.3671C>T p.A1224V | Missense Mutation (SNP) | VAF 14/247 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.52); called by muse, mutect2
- ERICH3 | c.2824G>A p.V942I | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.036); called by muse, mutect2
- ESPNL | c.1209C>A p.D403E | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ESX1 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.19); called by muse, mutect2
- EYS | c.5472G>T p.M1824I | Missense Mutation (SNP) | VAF 17/322 reads (5%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- EYS | c.5471T>A p.M1824K | Missense Mutation (SNP) | VAF 17/325 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- FAM135B | c.3542T>A p.M1181K | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.131); called by muse, mutect2
- FAM135B | c.3026T>C p.I1009T | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- FAM76B | c.110T>G p.I37S | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2
- FBXO48 | c.284T>A p.L95Q | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FLG | c.10112C>A p.S3371Y | Missense Mutation (SNP) | VAF 32/504 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- FLNC | c.7582G>T p.V2528L | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- FOXF1 | c.1108A>T p.T370S | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2
- FRY | c.6457A>G p.I2153V | Missense Mutation (SNP) | VAF 16/464 reads (3%) | SIFT tolerated (0.74); PolyPhen benign (0.02); called by muse, mutect2
- GABRB1 | c.504T>A p.Y168* | Nonsense Mutation (SNP) | VAF 16/494 reads (3%) | called by muse, mutect2
- GEMIN8 | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GGTLC2 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 15/346 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2
- GLE1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 21/293 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2
- GPRC6A | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- GREB1L | c.1589C>G p.S530C | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- GRIK2 | c.1920G>T p.W640C | Missense Mutation (SNP) | VAF 15/449 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HBD | c.178A>T p.K60* | Nonsense Mutation (SNP) | VAF 34/582 reads (6%) | called by muse, mutect2
- HIVEP1 | c.7413A>T p.Q2471H | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IER5L | c.423_428del p.A142_A143del | In Frame Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, varscan2
- IGKV1D-12 | c.194C>A p.A65D | Missense Mutation (SNP) | VAF 22/271 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- IGLC2 | c.321G>T p.*107Yext*36 | Nonstop Mutation (SNP) | VAF 27/892 reads (3%) | called by muse, mutect2
- INTS2 | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); called by muse, mutect2
- ITPR1 | c.4426G>T p.E1476* (on ENST00000354582; = p.E1461* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- JPH2 | c.1815G>T p.Q605H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- KCNB2 | c.1099A>G p.S367G | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- KCNH5 | c.758T>C p.V253A | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, mutect2
- KCNK13 | c.750C>A p.H250Q | Missense Mutation (SNP) | VAF 22/333 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- KDM5C | c.3958A>T p.R1320* | Nonsense Mutation (SNP) | VAF 55/230 reads (24%) | called by muse, mutect2, varscan2
- KIAA1549L | c.2018C>T p.S673L (on ENST00000321505; = p.S970L on NM_012194.3) | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- KIAA1755 | c.1934C>A p.P645H | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KIAA1755 | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 12/157 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- KIF1C | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRT72 | c.668C>A p.T223K | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KY | c.795T>A p.F265L | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.078); called by muse, mutect2
- LDB2 | c.794G>T p.S265I | Missense Mutation (SNP) | VAF 13/270 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.732); called by muse, mutect2
- LILRA5 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LIN9 | c.1564G>C p.G522R (on ENST00000366808 / NM_001270410.2; = p.G467R on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/270 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.132); called by muse, mutect2
- LOXHD1 | c.3572C>T p.T1191I | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LPA | c.3824A>T p.Y1275F | Missense Mutation (SNP) | VAF 28/551 reads (5%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); called by muse, mutect2
- MACROD2 | c.1210G>T p.D404Y (on ENST00000642719; = p.D376Y on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/312 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.646); called by muse, mutect2
- MCHR2 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- MED23 | c.1795G>T p.G599W | Missense Mutation (SNP) | VAF 26/689 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MICU3 | c.1349G>T p.S450I | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); called by muse, mutect2
- MLH3 | c.1723C>A p.H575N | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- MMP16 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- MS4A4A | c.145C>A p.H49N | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.073); called by muse, mutect2
- MTUS2 | c.1304G>T p.S435I | Missense Mutation (SNP) | VAF 34/256 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MUC16 | c.18441G>T p.L6147F | Missense Mutation (SNP) | VAF 21/367 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.13); called by muse, mutect2
- MUC7 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- MYO18B | c.4390C>G p.R1464G | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- MYO3A | c.4730G>T p.R1577M | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MYO5C | c.4688G>T p.C1563F | Missense Mutation (SNP) | VAF 25/526 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.65); called by muse, mutect2
- MYT1L | c.2386C>A p.P796T | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2
- NALCN | c.3319G>C p.A1107P | Missense Mutation (SNP) | VAF 31/353 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NALCN | c.2150G>C p.R717T | Missense Mutation (SNP) | VAF 27/326 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- NARS2 | c.92G>T p.R31L | Missense Mutation (SNP) | VAF 15/394 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.268); called by muse, mutect2
- NBEA | c.5087G>A p.G1696D | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.366); called by muse, mutect2
- NBPF12 | c.2581G>T p.E861* | Nonsense Mutation (SNP) | VAF 26/690 reads (4%) | called by muse, mutect2
- NEFM | c.766G>T p.V256L | Missense Mutation (SNP) | VAF 62/676 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.111); called by muse, mutect2
- NET1 | c.1498A>G p.I500V (on ENST00000355029 / NM_001047160.3; = p.I446V on NM_005863.5) | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.021); called by muse, mutect2
- NFATC4 | c.1268T>A p.V423E | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- NFE2L2 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- NKAIN1 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NLRP11 | c.1915C>A p.H639N | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NLRP8 | c.1788A>T p.K596N | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NPHS1 | c.11G>T p.G4V | Missense Mutation (SNP) | VAF 98/339 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NRAP | c.1428+2T>A p.X476_splice (on ENST00000359988 / NM_001322945.2; = p.X441_splice on NM_006175.4) | Splice Site (SNP) | VAF 10/190 reads (5%) | called by muse, mutect2
- NRXN2 | c.2559G>T p.M853I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- NUP210L | c.4684C>T p.L1562F | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.026); called by muse, mutect2
- NWD2 | c.3150G>T p.K1050N | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2
- OR2M2 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 32/365 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- OR2M2 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 34/485 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- OR2T27 | c.735G>T p.M245I | Missense Mutation (SNP) | VAF 30/242 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.074); called by muse, varscan2
- OR2W1 | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.879); called by muse, mutect2
- OR4C6 | c.696C>A p.H232Q | Missense Mutation (SNP) | VAF 25/370 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); called by muse, mutect2
- OR4S1 | c.236T>A p.M79K | Missense Mutation (SNP) | VAF 46/400 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- OR52K2 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.021); called by muse, mutect2
- OR5B2 | c.736G>T p.V246F | Missense Mutation (SNP) | VAF 51/469 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR5I1 | c.457G>T p.G153* | Nonsense Mutation (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- OTOG | c.8156T>A p.V2719E | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OTOP3 | c.751G>T p.G251C | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- OTUD6A | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- PAK1 | c.438A>T p.T146= | Splice Region (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- PAX6 | c.682+8A>T | Splice Region (SNP) | VAF 41/365 reads (11%) | called by muse, mutect2, varscan2
- PCDH11Y | c.430G>A p.V144I (on ENST00000400457 / NM_032973.2; = p.V133I on NM_032971.3) | Missense Mutation (SNP) | VAF 27/305 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHA1 | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 17/520 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHA2 | c.2187G>T p.E729D | Missense Mutation (SNP) | VAF 18/448 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); called by muse, mutect2
- PCDHB15 | c.1099C>A p.L367M | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PCDHB9 | c.1423G>C p.A475P | Missense Mutation (SNP) | VAF 22/563 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCLO | c.8209G>C p.E2737Q | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PDE6G | c.187+2T>A p.X63_splice | Splice Site (SNP) | VAF 34/329 reads (10%) | called by muse, mutect2, varscan2
- PDP1 | c.519G>C p.L173F | Missense Mutation (SNP) | VAF 47/466 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PKHD1 | c.10735G>T p.V3579L | Missense Mutation (SNP) | VAF 32/496 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2
- PLG | c.2357G>C p.R786P | Missense Mutation (SNP) | VAF 26/518 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.845); called by muse, mutect2
- POLK | c.1161C>G p.F387L | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); called by muse, mutect2
- POLR1E | c.606A>T p.E202D (on ENST00000377792 / NM_001282766.1; = p.E140D on NM_022490.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); called by muse, mutect2
- PSG9 | c.168C>A p.H56Q | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- PSMD4 | c.282+1G>T p.X94_splice | Splice Site (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- PTCHD3 | c.1832T>A p.L611* | Nonsense Mutation (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
- PTCRA | c.598A>T p.T200S | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); called by muse, mutect2
- RAB12 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RELN | c.2206T>A p.F736I | Missense Mutation (SNP) | VAF 51/761 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2
- RGPD4 | c.1009G>T p.G337C | Missense Mutation (SNP) | VAF 10/336 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- RHOJ | c.271C>G p.P91A | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2
- RIMKLB | c.683G>T p.S228I | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- RIMS2 | c.3850C>A p.Q1284K | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.355); called by muse, mutect2
- RUBCN | c.2869G>T p.E957* | Nonsense Mutation (SNP) | VAF 13/207 reads (6%) | called by muse, mutect2
- RYR1 | c.8450T>A p.I2817N | Missense Mutation (SNP) | VAF 44/379 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- SAR1A | c.150G>T p.L50F | Missense Mutation (SNP) | VAF 17/275 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.819); called by muse, mutect2
- SATB2 | c.1714G>T p.V572F | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2
- SEMA3C | c.1580C>A p.A527E | Missense Mutation (SNP) | VAF 18/257 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SERPINA6 | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 34/596 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.222); called by muse, mutect2
- SETBP1 | c.2386G>A p.E796K | Missense Mutation (SNP) | VAF 49/644 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); called by muse, mutect2
- SH2D1B | c.56T>A p.L19Q | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SIGLEC1 | c.3295G>T p.E1099* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- SIPA1L3 | c.2741G>T p.G914V | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2
- SLC22A7 | c.48C>A p.F16L | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- SLC2A14 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- SLC30A3 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 29/353 reads (8%) | called by muse, mutect2
- SLC6A2 | c.33G>T p.Q11H | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.547); called by muse, mutect2
- SMYD3 | c.488C>A p.S163Y (on ENST00000490107 / NM_001375962.1; = p.S104Y on NM_022743.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- SPATA31A1 | c.406C>A p.Q136K | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2
- SPATA31E1 | c.3885T>G p.D1295E | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.231); called by muse, mutect2
- SPTB | c.4684C>A p.L1562M | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPTBN2 | c.3600G>T p.M1200I | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.439); called by muse, mutect2
- SVEP1 | c.8855C>T p.P2952L | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYNE1 | c.23790+1G>T p.X7930_splice (on ENST00000367255 / NM_182961.4; = p.X7859_splice on NM_033071.3) | Splice Site (SNP) | VAF 12/294 reads (4%) | called by muse, mutect2
- SYT14 | c.600C>G p.C200W | Missense Mutation (SNP) | VAF 48/612 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.051); called by muse, mutect2
- TAAR8 | c.250G>T p.V84L | Missense Mutation (SNP) | VAF 11/257 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- TAF1 | c.3781C>T p.L1261F (on ENST00000373790 / NM_138923.4; = p.L1282F on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/242 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2
- TAGLN3 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 17/207 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.05); called by muse, mutect2
- TANC2 | c.4851G>T p.Q1617H | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- TATDN2 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- TEDC1 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.015); called by muse, mutect2
- TEX13C | c.1396G>T p.D466Y | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TMCC1 | c.1208A>G p.K403R (on ENST00000393238 / NM_001349268.2; = p.K79R on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- TNKS2 | c.1117G>T p.A373S | Missense Mutation (SNP) | VAF 17/195 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.042); called by muse, mutect2
- TNN | c.835C>A p.L279M | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, varscan2
- TNN | c.843C>A p.S281R | Missense Mutation (SNP) | VAF 35/327 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, varscan2
- TPO | c.184C>A p.L62I | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.111); called by muse, mutect2
- TRBV24-1 | c.89G>C p.R30T | Missense Mutation (SNP) | VAF 48/415 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- TRIM64B | c.686A>T p.Y229F | Missense Mutation (SNP) | VAF 17/454 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.244); called by muse, mutect2
- TRPV1 | c.1847G>T p.W616L | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- TSHR | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TSHZ3 | c.1643C>A p.P548H | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TTBK1 | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TXNDC8 | c.130-1G>T p.X44_splice | Splice Site (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- USH2A | c.320G>T p.S107I | Missense Mutation (SNP) | VAF 34/411 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- VAV3 | c.2306C>A p.P769Q | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- VGLL2 | c.951C>A p.S317R (on ENST00000326274 / NM_182645.3; = p.S143R on NM_153453.1) | Missense Mutation (SNP) | VAF 15/311 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- VPS13B | c.2897A>T p.Y966F | Missense Mutation (SNP) | VAF 32/512 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.393); called by muse, mutect2
- VPS13C | c.10737A>T p.Q3579H (on ENST00000644861 / NM_020821.3; = p.Q3536H on NM_017684.5) | Missense Mutation (SNP) | VAF 10/215 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- VPS8 | c.3749G>T p.G1250V (on ENST00000625842 / NM_001349294.1; = p.G1248V on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- WBP4 | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WNT9A | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- XAGE3 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- XYLT1 | c.1647C>G p.N549K | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- ZFPM2 | c.2377G>T p.G793* | Nonsense Mutation (SNP) | VAF 52/690 reads (8%) | called by muse, mutect2
- ZNF230 | c.52A>C p.T18P | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- ZNF311 | c.977G>C p.S326T | Missense Mutation (SNP) | VAF 13/262 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- ZNF383 | c.10G>T p.G4* | Nonsense Mutation (SNP) | VAF 45/255 reads (18%) | called by muse, mutect2, varscan2
- ZNF669 | c.335A>G p.K112R | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); called by muse, mutect2
- ZNF761 | c.2225G>T p.G742V | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2
- ABCA10 | c.2388A>G p.K796= | Silent (SNP) | VAF 15/175 reads (9%) | called by muse, mutect2
- ADGRF5 | c.1182G>A p.Q394= | Silent (SNP) | VAF 24/330 reads (7%) | catalogued as COSV51931675; called by muse, mutect2
- ADIG | c.144C>T p.S48= | Silent (SNP) | VAF 18/218 reads (8%) | called by muse, mutect2
- ANAPC2 | c.2073G>T p.L691= | Silent (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- ARHGEF26 | c.1866G>A p.E622= | Silent (SNP) | VAF 23/235 reads (10%) | catalogued as rs1043971555; called by muse, mutect2
- ATRNL1 | c.1266T>C p.D422= | Silent (SNP) | VAF 27/254 reads (11%) | called by muse, mutect2, varscan2
- B3GAT2 | c.84C>A p.R28= | Silent (SNP) | VAF 18/298 reads (6%) | called by muse, mutect2
- B9D2 | c.336G>T p.T112= | Silent (SNP) | VAF 25/155 reads (16%) | called by muse, mutect2, varscan2
- CACNA2D1 | c.1761A>T p.T587= (on ENST00000356253 / NM_001366867.1; = p.T568= on NM_000722.4) | Silent (SNP) | VAF 22/263 reads (8%) | catalogued as rs769358860; called by muse, mutect2
- COL11A1 | c.513G>T p.V171= | Silent (SNP) | VAF 16/405 reads (4%) | called by muse, mutect2
- COL5A2 | c.3675C>T p.P1225= | Silent (SNP) | VAF 14/212 reads (7%) | catalogued as COSV100880454; called by muse, mutect2
- COL6A5 | c.5985T>C p.I1995= (on ENST00000312481; = p.I1991= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/372 reads (10%) | called by muse, mutect2, varscan2
- COL9A1 | c.1968C>A p.P656= | Silent (SNP) | VAF 26/555 reads (5%) | called by muse, mutect2
- CX3CR1 | c.291C>T p.L97= | Silent (SNP) | VAF 34/486 reads (7%) | catalogued as rs1420321167; called by muse, mutect2
- CYP4F22 | c.309C>A p.V103= | Silent (SNP) | VAF 20/282 reads (7%) | catalogued as COSV54106533; called by muse, mutect2
- DEF8 | c.231C>T p.N77= (on ENST00000268676 / NM_207514.3; = p.N16= on NM_017702.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/252 reads (6%) | called by muse, mutect2
- DNAH9 | c.5484C>T p.A1828= | Silent (SNP) | VAF 10/200 reads (5%) | catalogued as rs1270140931; called by muse, mutect2
- EFR3A | c.405C>T p.S135= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as COSV54453623; called by muse, mutect2
- EPHB1 | c.702G>T p.V234= | Silent (SNP) | VAF 15/205 reads (7%) | called by muse, mutect2
- EYS | c.6306G>T p.V2102= | Silent (SNP) | VAF 18/355 reads (5%) | called by muse, mutect2
- EYS | c.3699G>T p.G1233= | Silent (SNP) | VAF 9/109 reads (8%) | called by muse, mutect2
- FBN2 | c.2286C>T p.I762= | Silent (SNP) | VAF 20/397 reads (5%) | catalogued as COSV99328288; called by muse, mutect2
- FREM2 | c.6462G>T p.G2154= | Silent (SNP) | VAF 14/342 reads (4%) | called by muse, mutect2
- G6PC2 | c.990C>T p.S330= | Silent (SNP) | VAF 22/368 reads (6%) | called by muse, mutect2
- HDAC9 | c.1572C>G p.G524= | Silent (SNP) | VAF 16/426 reads (4%) | called by muse, mutect2
- HSPA12A | c.402G>C p.L134= | Silent (SNP) | VAF 20/161 reads (12%) | catalogued as rs1554881555; called by muse, mutect2, varscan2
- ITM2A | c.309A>T p.G103= | Silent (SNP) | VAF 38/262 reads (15%) | called by muse, mutect2, varscan2
- KIF13B | c.1116G>T p.R372= | Silent (SNP) | VAF 24/213 reads (11%) | called by muse, mutect2
- KIF21B | c.4503C>T p.P1501= (on ENST00000422435 / NM_001252100.2; = p.P1488= on NM_017596.4) | Silent (SNP) | VAF 8/179 reads (4%) | catalogued as COSV59769619; called by muse, mutect2
- KIR2DL3 | c.702A>T p.P234= | Silent (SNP) | VAF 28/438 reads (6%) | called by muse, mutect2
- KLHL1 | c.2067C>A p.P689= | Silent (SNP) | VAF 18/283 reads (6%) | called by muse, mutect2
- LAMA2 | c.1725G>A p.R575= | Silent (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- LAMA4 | c.5430G>A p.L1810= (on ENST00000230538 / NM_001105206.3; = p.L1803= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/491 reads (5%) | called by muse, mutect2
- LRP1B | c.6189G>A p.K2063= | Silent (SNP) | VAF 25/220 reads (11%) | catalogued as COSV67199894; called by muse, mutect2, varscan2
- LRP2 | c.8109T>G p.S2703= | Silent (SNP) | VAF 23/614 reads (4%) | called by muse, mutect2
- MAGEL2 | c.2721C>T p.D907= | Silent (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2
- MTFR2 | c.570G>T p.R190= | Silent (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2
- MYCN | c.1365A>G p.L455= | Silent (SNP) | VAF 16/386 reads (4%) | catalogued as COSV55258415; called by muse, mutect2
- MYH1 | c.5025G>T p.L1675= | Silent (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- MYO18A | c.3381C>T p.V1127= | Silent (SNP) | VAF 24/300 reads (8%) | catalogued as rs777821484; called by muse, mutect2
- MYOM2 | c.825C>T p.H275= | Silent (SNP) | VAF 10/160 reads (6%) | catalogued as COSV50705819; called by muse, mutect2
- NEU4 | c.1293G>T p.G431= (on ENST00000391969 / NM_001167602.3; = p.G443= on NM_080741.4) | Silent (SNP) | VAF 9/156 reads (6%) | called by muse, mutect2
- NPR3 | c.483C>T p.A161= | Silent (SNP) | VAF 10/165 reads (6%) | called by muse, mutect2
- NRXN1 | c.2238C>T p.F746= | Silent (SNP) | VAF 30/412 reads (7%) | called by muse, mutect2
- OR2V1 | c.288G>T p.V96= | Silent (SNP) | VAF 10/218 reads (5%) | called by muse, mutect2
- OR2W3 | c.207G>A p.L69= | Silent (SNP) | VAF 25/254 reads (10%) | catalogued as rs1255724156, COSV64456382; called by muse, mutect2, varscan2
- OR3A1 | c.786T>C p.Y262= | Silent (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- OR52N5 | c.426T>A p.A142= | Silent (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- OR5T1 | c.681G>C p.L227= | Silent (SNP) | VAF 39/415 reads (9%) | catalogued as rs139648197; called by muse, mutect2, varscan2
- PAPPA2 | c.1986C>A p.P662= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV100866708, COSV100867070, COSV62774779; called by muse, mutect2
- PAPPA2 | c.3522C>A p.T1174= | Silent (SNP) | VAF 20/220 reads (9%) | called by muse, mutect2
- PCDH10 | c.231G>A p.E77= | Silent (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- PKHD1L1 | c.12267G>T p.P4089= | Silent (SNP) | VAF 26/272 reads (10%) | called by muse, mutect2
- PLTP | c.304C>A p.R102= | Silent (SNP) | VAF 40/434 reads (9%) | catalogued as rs144136911; called by muse, mutect2
- PTF1A | c.693C>A p.G231= | Silent (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2
- PYHIN1 | c.345T>C p.A115= | Silent (SNP) | VAF 25/318 reads (8%) | called by muse, mutect2
- RAB11FIP1 | c.2181G>T p.P727= | Silent (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- RABGEF1 | c.942C>T p.A314= (on ENST00000439720 / NM_001287061.2; = p.A301= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 11/264 reads (4%) | called by muse, mutect2
- RNF150 | c.99G>T p.V33= | Silent (SNP) | VAF 21/547 reads (4%) | catalogued as COSV60791245; called by muse, mutect2
- RNF6 | c.1317G>T p.G439= | Silent (SNP) | VAF 34/182 reads (19%) | called by muse, mutect2, varscan2
- RPS19 | c.423C>T p.A141= | Silent (SNP) | VAF 51/427 reads (12%) | called by muse, mutect2, varscan2
- RXFP2 | c.828G>A p.T276= | Silent (SNP) | VAF 22/328 reads (7%) | catalogued as rs929792385, COSV53634693; called by muse, mutect2
- SERPINB3 | c.267G>A p.L89= | Silent (SNP) | VAF 33/456 reads (7%) | called by muse, mutect2
- SLAMF9 | c.360T>C p.S120= | Silent (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2
- SLC22A8 | c.1473C>T p.F491= | Silent (SNP) | VAF 14/202 reads (7%) | catalogued as COSV100268171, COSV60325231; called by muse, mutect2
- SLC23A3 | c.879C>T p.P293= (on ENST00000409878 / NM_001144889.2; = p.P261L on NM_144712.5) | Silent (SNP) | VAF 10/78 reads (13%) | called by muse, mutect2, varscan2
- SLC29A3 | c.939C>A p.T313= | Silent (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2, varscan2
- SNAPC3 | c.1119A>G p.P373= | Silent (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2, varscan2
- SOCS3 | c.66C>A p.L22= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV58269908; called by mutect2, varscan2
- SOX18 | c.264C>A p.P88= | Silent (SNP) | VAF 14/329 reads (4%) | catalogued as COSV100450555; called by muse, mutect2
- SPTBN2 | c.3507C>T p.A1169= | Silent (SNP) | VAF 8/188 reads (4%) | called by muse, mutect2
- TENM4 | c.6594T>A p.A2198= | Silent (SNP) | VAF 22/464 reads (5%) | called by muse, mutect2
- TEX13C | c.531T>A p.T177= | Silent (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- TG | c.7866G>A p.L2622= | Silent (SNP) | VAF 15/214 reads (7%) | called by muse, mutect2
- THBS2 | c.2685C>A p.A895= | Silent (SNP) | VAF 24/456 reads (5%) | catalogued as COSV64677442; called by muse, mutect2
- TMEM132D | c.2799C>A p.V933= | Silent (SNP) | VAF 48/405 reads (12%) | called by muse, mutect2, varscan2
- TNR | c.1491G>T p.S497= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV54870051; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1459C>T p.L487= | Silent (SNP) | VAF 16/205 reads (8%) | called by muse, mutect2
- TRIM48 | c.96C>A p.P32= | Silent (SNP) | VAF 48/634 reads (8%) | catalogued as rs1447783403; called by muse, mutect2
- USP27X | c.756C>T p.N252= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as rs1218792823; called by muse, mutect2, varscan2
- USP5 | c.966G>T p.G322= | Silent (SNP) | VAF 15/212 reads (7%) | called by muse, mutect2
- VPS72 | c.574C>A p.R192= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as COSV54859916; called by muse, mutect2, varscan2
- XYLT1 | c.1932G>C p.L644= | Silent (SNP) | VAF 24/350 reads (7%) | called by muse, mutect2
- YPEL5 | c.129T>C p.F43= | Silent (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- ZNF304 | c.1344G>T p.V448= | Silent (SNP) | VAF 9/238 reads (4%) | called by muse, mutect2
- ZNF536 | c.717C>A p.T239= | Silent (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- AC034198.1 | n.186C>A | RNA (SNP) | VAF 32/380 reads (8%) | called by muse, mutect2
- AC073316.1 | n.126G>T | RNA (SNP) | VAF 10/155 reads (6%) | called by muse, mutect2
- AC097518.1 | n.66C>A | RNA (SNP) | VAF 14/305 reads (5%) | called by muse, mutect2
- AC139769.1 | n.214-4103G>A | Intron (SNP) | VAF 22/482 reads (5%) | called by muse, mutect2
- ACE | c.3381-25G>T | Intron (SNP) | VAF 33/323 reads (10%) | called by muse, mutect2
- AL772337.1 | n.858-161C>A | Intron (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- ANKRD26 | c.1635+2079T>A | Intron (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- ARFGAP1 | c.627+243G>T | Intron (SNP) | VAF 15/138 reads (11%) | catalogued as rs554241137, COSV62263945; called by muse, mutect2, varscan2
- CMA1 | c.*27G>A | 3'UTR (SNP) | VAF 18/194 reads (9%) | called by muse, mutect2
- CNTN4 | c.1486+40G>T | Intron (SNP) | VAF 18/220 reads (8%) | called by muse, mutect2
- COL7A1 | c.7104+30G>T | Intron (SNP) | VAF 37/367 reads (10%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*5059A>G | 3'UTR (SNP) | VAF 12/184 reads (7%) | called by muse, mutect2
- CYP4F11 | c.-1-51G>T | Intron (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- DCDC1 | c.5074-2177A>G | Intron (SNP) | VAF 13/100 reads (13%) | called by muse, mutect2, varscan2
- DCT | c.1180-2068T>A | Intron (SNP) | VAF 11/221 reads (5%) | called by muse, mutect2
- DENND1B | c.83-20589G>T | Intron (SNP) | VAF 30/386 reads (8%) | called by muse, mutect2
- EPHB6 | c.1865+12C>T | Intron (SNP) | VAF 29/380 reads (8%) | called by muse, mutect2
- FAM153CP | n.201-2310G>A | Intron (SNP) | VAF 22/384 reads (6%) | called by muse, mutect2
- FARS2 | c.904+499G>T | Intron (SNP) | VAF 24/342 reads (7%) | called by muse, mutect2
- GABRG2 | c.1248+275G>T | Intron (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- GABRG2 | c.1249-30G>C | Intron (SNP) | VAF 13/208 reads (6%) | called by muse, mutect2
- GDAP1 | c.*1015A>G | 3'UTR (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- GH1 | c.171+13G>A | Intron (SNP) | VAF 15/239 reads (6%) | catalogued as rs1193129189; called by muse, mutect2
- IGFN1 | c.1242-1823A>T | Intron (SNP) | VAF 30/426 reads (7%) | called by muse, mutect2
- IGHD1-1 | chr14:105922248 G>T | 5'Flank (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- KCNT1 | c.-19G>A | 5'UTR (SNP) | VAF 14/224 reads (6%) | called by muse, mutect2
- LINC01169 | n.70C>T | RNA (SNP) | VAF 13/160 reads (8%) | called by muse, mutect2
- MACROD2 | c.859+799C>A | Intron (SNP) | VAF 20/331 reads (6%) | called by muse, mutect2
- MARCHF1 | c.242+323C>A | Intron (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- MUCL3 | c.947-140T>C | Intron (SNP) | VAF 20/248 reads (8%) | catalogued as rs1417319373; called by muse, mutect2
- MYCT1 | c.*524G>T | 3'UTR (SNP) | VAF 16/223 reads (7%) | called by muse, mutect2
- NABP1 | c.302+556G>T | Intron (SNP) | VAF 19/271 reads (7%) | called by muse, mutect2
- NCAN | c.*161C>A | 3'UTR (SNP) | VAF 24/366 reads (7%) | called by muse, mutect2
- NELFCD | c.231-24A>G | Intron (SNP) | VAF 32/359 reads (9%) | called by muse, mutect2
- NME1 | c.228+67G>C | Intron (SNP) | VAF 36/446 reads (8%) | called by muse, mutect2
- PAMR1 | c.-5C>A | 5'UTR (SNP) | VAF 33/231 reads (14%) | called by muse, mutect2, varscan2
- PAX8 | c.-60G>T | 5'UTR (SNP) | VAF 11/174 reads (6%) | called by muse, mutect2
- PPEF2 | c.747-22C>T | Intron (SNP) | VAF 9/140 reads (6%) | called by muse, mutect2
- PPFIA4 | c.-248C>G | 5'UTR (SNP) | VAF 18/152 reads (12%) | catalogued as rs1462751650; called by muse, mutect2, varscan2
- PRDM11 | c.657-5881G>T | Intron (SNP) | VAF 30/379 reads (8%) | called by muse, mutect2
- RAB18 | c.*383C>T | 3'UTR (SNP) | VAF 26/438 reads (6%) | catalogued as rs1394941161; called by muse, mutect2
- SCML2P1 | chr18:6928477 C>T | 3'Flank (SNP) | VAF 15/262 reads (6%) | called by muse, mutect2
- SIGLEC14 | c.*31T>A | 3'UTR (SNP) | VAF 43/289 reads (15%) | called by muse, mutect2, varscan2
- SNORD108 | n.33G>T | RNA (SNP) | VAF 10/193 reads (5%) | called by muse, mutect2
- SNORD109A | chr15:25042052 C>T | 3'Flank (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- SNORD115-26 | n.79G>T | RNA (SNP) | VAF 24/454 reads (5%) | called by muse, mutect2
- TGIF2LY | c.*48C>A | 3'UTR (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- TPT1 | c.102+179C>T | Intron (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- TRPA1 | c.1365-37A>T | Intron (SNP) | VAF 17/509 reads (3%) | called by muse, mutect2
- USH2A | c.7301-16C>A | Intron (SNP) | VAF 36/590 reads (6%) | catalogued as rs2185317; called by muse, mutect2
- USH2A | c.4627+56T>C | Intron (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2
- Unknown | chr16:27288909 A>G | IGR (SNP) | VAF 9/166 reads (5%) | called by muse, mutect2
- ZNF462 | c.6013-99G>A | Intron (SNP) | VAF 21/277 reads (8%) | catalogued as rs769509619; called by muse, mutect2
- ZNF849P | n.993A>T | RNA (SNP) | VAF 25/180 reads (14%) | called by muse, mutect2, varscan2
